Somatic mutation profile of tumor specimen TCGA-FY-A3WA-01A (aliquot TCGA-FY-A3WA-01A-11D-A22D-08) from TCGA case TCGA-FY-A3WA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 52.0 years (18,993 days).
Specimen TCGA-FY-A3WA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abd611f5-6184-4ffc-a853-8298e0629478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3WA-10A (Blood Derived Normal), aliquot TCGA-FY-A3WA-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da22f5f2-9b0b-4b2f-81f4-c9f6a83b4b4a

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L12 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 25/437 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs764515780, COSV55864299; called by muse, mutect2
- CLIC6 | c.2011A>G p.R671G (on ENST00000360731 / NM_001317009.2; = p.R653G on NM_053277.3) | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62448940; called by muse, mutect2
- TBC1D14 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs780573851, COSV68986879; called by muse, mutect2, varscan2
- LYZL2 | c.339C>T p.D113= (on ENST00000375318; = p.D67= on NM_183058.3) | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs374503421; called by muse, mutect2, varscan2
